CPTAC case C3N-02579 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/89b2249f-eb4c-4e81-a844-f7fcf1a25cd0

Demographics
Sex at birth: female; Race: asian; Year of birth: 1965; Vital status: Dead; Days to death: 358 days; Year of death: 2018; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 51.8 years (18,922 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 358 days; Progression or recurrence: yes; Days to last follow up: 245 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 0.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 9; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (2 entries)
- Days to follow up: 245 days; Disease response: Progressive Disease; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 245 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 195 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 55 kg; Height: 156 cm; BMI: 22.6; Comorbidities: Pancreatitis.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02579-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -5 days; Initial weight: 138 mg; Time between clamping and freezing: 19 minutes; Time between excision and freezing: 11 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02579-22: Section location: Head; Percent tumor nuclei: 30; Percent necrosis: 0.
- Sample C3N-02579-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -5 days; Method of sample procurement: Blood Draw.
